Somatic mutation profile of tumor specimen TARGET-20-PASGEM-03A (aliquot TARGET-20-PASGEM-03A-01D) from TARGET case TARGET-20-PASGEM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.7 years (3,192 days).
Specimen TARGET-20-PASGEM-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ee38ba6-8d83-42f1-a9ef-53428f7b97de.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASGEM-14A (Bone Marrow Normal), aliquot TARGET-20-PASGEM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a692ff41-5a17-45f0-a6e5-f9c7498b9ff1

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 85/201 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 101/228 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.405_406insCTCACTTCGGAACTGACAAAC p.L136_S137insTSELTNL | In Frame Ins (INS) | VAF 38/131 reads (29%) | called by mutect2, pindel, varscan2
- LIN28A | c.*614C>T | 3'UTR (SNP) | VAF 82/203 reads (40%) | catalogued as rs993958808; called by muse, mutect2, varscan2
